Somatic mutation profile of tumor specimen 0DB2AS from CCDI case PBBKCI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.6 years (3,145 days).
Specimen 0DB2AS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52f2f80b-c5ee-4b36-b572-1fe10d9c4d80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB2AN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b5c0439-51f4-4f47-a91f-d6377ba03484

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 2, 5'UTR 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAXC | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 128/594 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs746691175, COSV67603781; called by muse, mutect2
- FOXK1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 127/789 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); catalogued as rs373966273; called by muse, mutect2, varscan2
- HIVEP3 | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 62/494 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs149958873; called by muse, mutect2, varscan2
- KRT38 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 33/656 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs199726500; called by muse, mutect2
- MED12L | c.5531C>T p.S1844F | Missense Mutation (SNP) | VAF 51/658 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.678); catalogued as rs904715198, COSV56401360; called by muse, mutect2
- NLRP5 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 111/490 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs374153940; called by muse, mutect2, varscan2
- NME7 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 73/558 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs759709180, COSV63169725; called by muse, mutect2, varscan2
- NTRK3 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371959662, COSV62300789, COSV62310747; called by muse, mutect2, varscan2
- TEC | c.1750C>T p.L584F | Missense Mutation (SNP) | VAF 60/827 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VIRMA | c.1842G>A p.L614= | Silent (SNP) | VAF 97/385 reads (25%) | called by muse, mutect2, varscan2
- AGK | c.1131+49C>T | Intron (SNP) | VAF 44/167 reads (26%) | catalogued as rs758600654; called by muse, mutect2, varscan2
- CYLD | c.*81G>A | 3'UTR (SNP) | VAF 4/72 reads (6%) | catalogued as rs1275758699; called by muse, mutect2
- ZBTB40 | c.2833+39C>G | Intron (SNP) | VAF 16/474 reads (3%) | called by muse, mutect2
- ZSWIM2 | c.-21C>A | 5'UTR (SNP) | VAF 133/426 reads (31%) | called by muse, mutect2, varscan2
